Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A1O9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A1O9-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

PATIENT: [REDACTED]

Hospital No.:
Date of Birth:
Soc. Sec. No.:
Location:

Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

1CB-0-3
Carcinoma, squamous cell, Nos 8070/3
Site: cervix, Nos 2539 3/4/11

DIAGNOSIS:

- 1: BLADDER FLAP, BIOPSY:
- Fibrous connective tissue with granulation tissue, inflammation, and reactive mesothelial cells
- No definite tumor identified
- 2: RIGHT OVARY, OOPHORECTOMY WITH FROZEN SECTION:
- Ovarian cystadenofibroma with squamous cell carcinoma (metastatic vs. direct extension from uterus) (see Comment)
- Fallopian tube adherent to tumor mass
- 3: UTERUS, LEFT FALLOPIAN TUBE AND OVARY, TERMINAL ILEUM, APPENDIX, AND CECUM, RESECTION:
- Extensive involvement of uterus by invasive squamous cell carcinoma, moderately-poorly differentiated (presumably of cervical origin), with involvement of cervical transition zone (with foci of squamous cell carcinoma in situ), anterior and posterior lower uterine segment, and endometrium (with diffuse replacement of mucosal surfaces by squamous carcinoma in situ)
- Invasive carcinoma invades into and through cervical stroma and myometrium (with replacement of much of the normal uterine wall by tumor cells)
- Invasive carcinoma present on and along serosal surfaces
- Invasive carcinoma present at paracervical soft tissue margins of resection and adjacent to distal vaginal cuff margins of resection (considered positive)
- Left and right parametrial tissue, negative for malignancy
- Extensive tumor-associated necrosis
- Carcinoma invades through serosal surface in fundic region of uterus with extension into bowel wall (in region of terminal ileum), with invasion through muscularis propria of terminal ileum and vermiform appendix
- Proximal and distal margins of resection (of ileocelectomy), negative for malignancy
- Angiolymphatic vascular space invasion identified in uterine sections
- Left fallopian tube and ovary, negative for malignancy
- Approximately 15 pericolic lymph nodes, negative for malignancy (0/15)
- 4: ADDITIONAL CECUM, RESECTION:
- Portion of cecum, negative for malignancy
- Approximately four pericolic lymph nodes, negative for malignancy (0/4)
- 5: CECAL LYMPH NODE, BIOPSY:
- Two lymph nodes, negative for malignancy (0/2)

[page 2 of 7]
6: RIGHT PELVIC LYMPH NODE, BIOPSY:

-One lymph node, negative for malignancy (0/1)

7: LEFT PERIURETHRAL TISSUE, BIOPSY:

-Portion of crushed (distorted) fibroadipose tissue with squamous cell carcinoma

-Fibroadipose tissue with acute hemorrhage

-One lymph node, negative for malignancy (0/1)

COMMENT: Gross and microscopic evaluation of the hysterectomy specimen demonstrates diffuse involvement (and replacement) of mucosal surfaces (endocervical, lower uterine segment and endometrial), cervical stromal tissues and myometrium by squamous cell carcinoma. Sections from the transition zone of the cervix demonstrate previous biopsy site changes in addition to multifocal areas of squamous cell carcinoma in situ. These changes are also seen in most sections from the lower uterine segment and endometrium. Invasive squamous cell carcinoma erodes through the cervical stroma and is present at the paracervical soft tissue margins of resection, as well as adjacent to the distal (paravaginal) margins of resection (considered positive margins. The myometrium is diffusely involved by invasive squamous cell carcinoma, with extension to the serosal surfaces. In the right fundic region, carcinoma invades into the serosal surfaces of the terminal ileum and appendix with extension through the muscularis propria and towards the mucosal surfaces. The right oophorectomy specimen demonstrates invasive squamous cell carcinoma (similar to that seen elsewhere), secondarily involving a pre-existing cystadenofibroma. The possibility of direct spread of the carcinoma from the uterus to the right ovary cannot be excluded (versus metastatic spread or "co-synchronous primary". The tumor appears high grade with significant tumor-associated necrosis, angiolymphatic vascular space invasion and a high rate of mitotic activity.

=====

HISTORY: Cervical carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: BLADDER FLAP

Labeled "bladder flap" and received in formalin is a 0.7 x 0.5 x 0.3 cm portion of pale tan-pink soft tissue.

A. All embedded - 1

2: RIGHT OVARY AND FROZEN SECTION

Labeled "right ovary and FS", received fresh in the Operating Room and subsequently fixed in formalin, is a 6.0 x 5.5 x 4.5 cm cystically dilated ovary. The surface of the ovary is tan-pink with numerous red-tan hemorrhagic soft tissue adhesions and a 2.5 x 2.0 cm defect which exposes a pale tan friable tumor. Cut section of the ovary reveals a 2.5 x 2.4 cm solid pale tan papillated nodular lesion in the lining of the ovary with adjacent attached 1.5 x 1.2 x 1.0 cm cyst. The cyst is filled with cloudy pale yellow fluid. Cut section of the papillated solid area corresponds to a 4.0 x 4.0 x 3.5 cm semi-firm tan-yellow mass which extends to the previously described defect. Focal areas of hemorrhage and necrosis are present throughout the mass. The remaining lining of the cyst is generally smooth and glistening, pale tan-pink with prominent small vessels and no other discrete vessels or solid areas grossly identified. The uninvolved cyst lining is approximately 0.2 cm in average thickness. No normal ovarian parenchyma is grossly identified. Representative sections are submitted.

B. Frozen section remnant - 1

[page 3 of 7]
- C. Lesion with adjacent disrupted capsule - 1
- D. Lesion with adjacent disrupted capsule - 2
- E. Lesion with disrupted capsule - 1
- F. Lesion with adjacent cyst - 1
- G. Uninvolved cyst lining - 4
- OO. Right fallopian tube - 2

3: UTERUS WITH ILEUM AND CECUM

Labeled "uterus with ileum and cecum", received fresh in the Operating Room and subsequently fixed in formalin, is a 340 gram total abdominal hysterectomy with attached left fallopian tube and ovary, ileum, cecum, and appendix. The uterus is 10.0 cm from fundus to cervix, 6.5 cm from cornu to cornu, and 5.5 cm from anterior to posterior. The serosa is red-tan and diffusely roughened with hemorrhagic red-tan soft tissue adhesions. The segment of ileum and a portion of the appendix are adhered to the right fundic region of the uterus with a large amount of hemorrhagic soft tissue adhesions and indurated adipose tissue. The anterior fundic region is also diffusely nodular due to underlying tumor. The nodules range from 1.0 to 3.5 cm in greatest dimension and coalesce with one another. A small amount of parametrium is attached to the uterus and is approximately 2.0 cm in maximum width on the right and 1.5 cm in maximum width on the left. The cervix is 3.4 x 2.8 cm in the area of the ectocervical region. The ectocervix is diffusely disrupted with no normal cervical epithelium grossly identified. No vaginal cuff is grossly identified. The endocervical canal is 3.5 cm long, lined by velvety hyperemic mucosa. Cut section of the cervix reveals tan-pink, somewhat fibrotic stroma. The endometrial cavity is 4.2 cm long from fundus to upper endocervical canal with a maximum width of 3.5 cm. The endometrium is entirely obliterated with a somewhat papillated tan-pink diffusely hemorrhagic lesion which grossly extends to, and involves, the lower uterine segment. Focal areas of necrosis are present throughout the endometrial lesion. No normal endometrium is grossly identified. The uterine wall is 3.0 cm in maximum thickness. Cut section of the myometrium reveals a semi-firm pale tan appearance and is continuous with the endometrial tumor. The entire myometrium has a maximum thickness of 3.0 cm and is involved by tumor. Diffuse necrosis is also present throughout. The lesion grossly extends to and disrupts the serosa, predominantly along the posterior uterine wall. The tumor in the region of the fundus also grossly invades the serosa of the segment of terminal ileum. The left fallopian tube is 5.5 cm long and 0.6 cm in maximum diameter. No fimbria is grossly identified. A 1.0 x 0.8 x 0.7 cm orange-tan nodule is present in the region of the fimbria. Cut section of the fallopian tube reveals a central patent lumen. The left ovary is red-tan, generally smooth and 2.5 x 1.5 x 1.0 cm. Cut section of the left ovary reveals normal ovarian parenchyma with several white-tan scattered corpora albicantia identified. No tumor is grossly identified. The segment of terminal ileum is 20 cm long with an average diameter of 2.5 cm. The serosa of the terminal ileum is red-tan, diffusely granular with numerous soft tissue adhesions adhering it to the fundus of the uterus. The attached mesenteric adipose tissue has a maximum width of 6.0 cm and is also adhered to the posterior fundic region of the uterus. The segment of terminal ileum is opened along the antimesenteric border revealing pale tan, normally folded mucosa. Cut section of the wall of the terminal ileum in the region of the adhesion to the fundus of the uterus reveals infiltrative tumor which grossly invades the muscularis of the terminal ileum, but does not grossly invade the mucosa of the terminal ileum. The wall of the terminal ileum is approximately 0.6 cm in maximum dimension. The appendix is 7.0 cm long and 0.8 cm in maximum diameter. The attached mesoappendix has a maximum width of 1.5 cm and is diffusely hemorrhagic and indurated. The serosa of the appendix is red-tan and diffusely granular with multiple soft tissue adhesions along the proximal 2 cm adhering it to the fundic region of the uterus. Cut section of the appendix reveals that the uterine tumor grossly involved the serosa of the appendix, but does not involve the wall

[page 4 of 7]
of the appendix. A central patent 0.3 cm maximum diameter lumen is identified. The segment of cecum, including ileocecal valve, is 7.0 cm long with a maximum diameter of 4.5 cm. The serosa of the cecum is red-tan with multiple red-tan hemorrhagic soft tissue adhesions. No discrete areas of tumor nodules are grossly identified. The segment of cecum is opened along the antimesenteric border revealing slightly hyperemic tan-red normally folded mucosa. The wall of the cecum is approximately 0.6 cm in maximum width. The cecum and ileocecal valve appear grossly free of tumor. Dissection of the pericolic and adipose tissue reveals several tan-pink lymph nodes ranging from 0.2 to 0.7 cm. Representative sections are submitted.

- H. Proximal and distal perpendicular margin of terminal ileum and cecum - 2
- I. Anterior cervix - 2
- J. Posterior cervix - 2
- K,L. Anterior lower uterine segment - 1 each
- M,N. Posterior lower uterine segment - 1 each
- O-R. Anterior corpus uterus with lesion (inferior to superior) - 1 each
- S. Anterior fundic lesion - 2
- T-W. Posterior corpus uterus (inferior to superior) - 1 each
- X. Left fallopian tube and ovary - 4
- Y. Right parametrium - 3
- Z. Left parametrium
- AA. Terminal ileum with lesion - 1
- BB. Terminal ileum with lesion - 1
- CC. Appendix - 3
- DD. Appendix with tumor - 2
- EE. Ileocecal valve - 1
- FF. Uninvolved terminal ileum and cecum - 2
- GG. 7)
- HH. 7) Lymph nodes
- II. 6)

4: ADDITIONAL CECUM

Labeled "additional cecum" and received in formalin is a 4.0 cm long segment of colon with an average diameter of 3.2 cm. A small amount of pericolic adipose tissue is present and is 2.5 cm in maximum width. The serosa of the cecum is red-tan with several red-tan hemorrhagic soft tissue adhesions. No discrete tumor nodules are identified. The segment of colon is opened along the antimesenteric border revealing tan, normally folded mucosa. The wall of the colon is approximately 0.6 cm in maximum thickness. No discrete lesions are identified. Dissection of the attached pericolic adipose tissue reveals several tan-pink lymph nodes ranging from 0.1 to 0.3 cm. Representative sections are submitted.

- JJ. Colonic segments with both resection margins - 2
- KK. Lymph nodes - 8

5: CECAL LYMPH NODE

Labeled "cecal lymph node" and received in formalin are two 0.3 and 0.4 cm tan lymph nodes.

- LL. All embedded - 2

6: RIGHT PELVIC LYMPH NODE

Labeled "right pelvic lymph node" and received in formalin is a 1.2 x 0.6 x 0.5 cm tan-pink lymph node.

- MM. All embedded - 2

7: LEFT PERIURETERAL BIOPSY

Labeled "left periureteral biopsy" and received in formalin is a 1.8 x 1.5 x 0.4 cm aggregate of red-tan tissue fragments.

- NN. All embedded - Multiple

[page 5 of 7]
HISTORY AND PHYSICAL EXAMINATION
DATE OF ADMISSION:

ATTENDING PHYSICIAN:

REASON FOR ADMISSION: The patient is scheduled for surgery on
This is a preoperative history and physical for a
laparoscopy, possible laparotomy.

HISTORY OF PRESENT ILLNESS: The patient is a 76-year-old gravida 2,
para 2 female presenting with a pelvic mass and Pap smear consistent
with a malignancy having adenocarcinoma on Pap. The patient with no
hormone replacement therapy. The patient also with complaints of some
weight loss and severe back pain for about two weeks now. Weight loss
of 19-20 pounds over the last six months. Also with some vaginal
bleeding occasionally. Pelvic ultrasound done revealed a
complex cystic and solid right adnexal mass and a fibroid on the
anterior fundus, a small amount of fluid in the endometrial canal was
noted and an endometrial start measured 0.77 cm. A CT scan of the
abdomen done revealed a right pelvic kidney and a few tiny
renal cysts, an infiltrate in the inferior right lower lobe of the
lung. Possible benign splenic lesions. There was no ascites noted.
There was also noted to be a complex cystic and solid mass of the
pelvis. Pap smear done revealed malignant epithelial cells
with squamous and glandular differentiation. CEA-125 level was 21.

PAST MEDICAL HISTORY:

She has not had a history of diabetes, asthma
or tuberculosis.

PAST SURGICAL HISTORY: Negative.

MEDICATIONS: Ativan, Paxil, some type of sleeping pill and Vicodin.

ALLERGIES: No known drug allergies.

HABITS: The patient is a smoker, smoked two packs per day for about
50-60 years, now is decreased to one pack per day. She does not drink
any ethanol.

SOCIAL HISTORY: The patient is widowed, was from

FAMILY HISTORY: Negative for cancer.

REVIEW OF SYSTEMS: The patient has a lot of anxiety, otherwise
negative.

[page 6 of 7]
Gross dictated by

OPERATIVE CONSULT (GROSS):
Part 3. Extensive uterine tumor

OPERATIVE CONSULT (FROZEN):
FROZEN SECTION (PART 2):
-Right ovary with nests of tumor cells consistent with squamous
cell carcinoma

Special Studies: Frozen Section, Serial Sections, mucin, PAS, PAS
with diastase
See Also:

Pathologist

I, . M.D., the pathologist of record, have
personally examined the specimen, interpreted the
results, reviewed this report and signed it electronically.
Date Finalled:

[page 7 of 7]
The patient is a 76-year-old female with a possible uterine versus primary cervical or vaginal cancer. She is to be admitted and to undergo laparoscopy and possible laparotomy.

PRELIMINARY UNVERIFIED REPORT

Source: NCI Genomic Data Commons file 0c117211-511b-4cd1-986d-eeb9273c978b (TCGA-DS-A1O9.DDC9EA73-6412-4D20-A422-0F57A8925536.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).